Somatic mutation profile of tumor specimen TCGA-D5-5540-01A (aliquot TCGA-D5-5540-01A-01D-1650-10) from TCGA case TCGA-D5-5540, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cecum; AJCC pathologic stage: Stage IIA; Age at diagnosis: 73.8 years (26,972 days).
Specimen TCGA-D5-5540-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7b3311ac-4978-430a-9176-c398116a3aaa.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D5-5540-10A (Blood Derived Normal), aliquot TCGA-D5-5540-10A-01D-1650-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/048d45ea-9522-447d-b4d1-802af41074e1

The open-access MAF lists 121 somatic variants for this specimen: 84 protein-altering or splice-affecting, 36 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 78, Silent 36, Nonsense Mutation 2, Splice Region 2, Frame Shift Del 1, Frame Shift Ins 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KCNH5 | c.980G>A p.R327H | Missense Mutation (SNP) | VAF 13/17 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs587777164, CM1310653, COSV59758318, COSV59758899; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 144/291 reads (49%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.241G>A p.E81K | Missense Mutation (SNP) | VAF 75/87 reads (86%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519929, CM126687, COSV55873676, COSV55913749; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 38/48 reads (79%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ADGRL1 | c.4261G>A p.E1421K (on ENST00000340736 / NM_001008701.3; = p.E1416K on NM_014921.5) | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.837); catalogued as rs764585021, COSV61564445; called by mutect2, varscan2
- ALPK2 | c.1769C>T p.A590V | Missense Mutation (SNP) | VAF 163/211 reads (77%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as rs1410165948, COSV64492484; called by muse, mutect2, varscan2
- APC | c.4152dup p.S1385* | Frame Shift Ins (INS) | VAF 158/232 reads (68%) | catalogued as COSV57402265; called by mutect2, pindel, varscan2
- AR | c.2315A>G p.N772S | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.959); catalogued as COSV65955796; called by muse, mutect2
- ARMC4 | c.55G>T p.G19* | Nonsense Mutation (SNP) | VAF 92/183 reads (50%) | catalogued as COSV59462231; called by muse, varscan2
- BDH2 | c.634G>A p.A212T | Missense Mutation (SNP) | VAF 196/341 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.499); catalogued as rs1421023724, COSV56478221; called by muse, mutect2, varscan2
- BDNF | c.379C>T p.R127W | Missense Mutation (SNP) | VAF 27/58 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59234777; called by muse, mutect2, varscan2
- BOD1L1 | c.2522A>G p.K841R | Missense Mutation (SNP) | VAF 195/314 reads (62%) | SIFT tolerated (0.12); PolyPhen benign (0.061); catalogued as COSV50010634; called by muse, mutect2, varscan2
- BPTF | c.4566A>T p.E1522D | Missense Mutation (SNP) | VAF 57/137 reads (42%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as COSV58836114; called by muse, mutect2, varscan2
- CARD6 | c.1613G>T p.S538I | Missense Mutation (SNP) | VAF 274/701 reads (39%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.564); catalogued as COSV54565799; called by muse, mutect2, varscan2
- CCDC88A | c.2722C>T p.R908C | Missense Mutation (SNP) | VAF 245/573 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55060452; called by muse, mutect2, varscan2
- CD109 | c.794C>T p.T265M | Missense Mutation (SNP) | VAF 161/381 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.776); catalogued as rs780970981, COSV54648599; called by muse, mutect2, varscan2
- CNR1 | c.91G>A p.E31K | Missense Mutation (SNP) | VAF 92/202 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.059); catalogued as rs770413069, COSV62987020; called by muse, mutect2, varscan2
- CORO1A | c.418C>A p.H140N | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.973); catalogued as rs1341907285, COSV54630372; called by muse, mutect2, varscan2
- CSF2RA | c.614T>A p.F205Y | Missense Mutation (SNP) | VAF 184/467 reads (39%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.99); catalogued as COSV62624415; called by muse, mutect2, varscan2
- CWH43 | c.818C>T p.A273V | Missense Mutation (SNP) | VAF 32/166 reads (19%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as rs747730162, COSV56938295; called by muse, mutect2, varscan2
- CYLC1 | c.1871T>A p.L624H | Missense Mutation (SNP) | VAF 214/246 reads (87%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV61411621; called by muse, mutect2, varscan2
- CYP46A1 | c.426C>A p.D142E | Missense Mutation (SNP) | VAF 30/37 reads (81%) | SIFT deleterious (0.01); PolyPhen benign (0.025); catalogued as rs1277328893, COSV55894218; called by muse, mutect2, varscan2
- DISP1 | c.4214C>T p.T1405M | Missense Mutation (SNP) | VAF 83/203 reads (41%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.057); catalogued as rs776835311, COSV52655877; called by muse, mutect2, varscan2
- ENC1 | c.1736C>T p.A579V | Missense Mutation (SNP) | VAF 60/169 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.954); catalogued as COSV56629467; called by muse, mutect2, varscan2
- EXD3 | c.1991C>T p.A664V | Missense Mutation (SNP) | VAF 49/120 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765802505, COSV59805172; called by muse, mutect2, varscan2
- FABP2 | c.286C>T p.R96W | Missense Mutation (SNP) | VAF 72/112 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs753335773, COSV56788432; called by muse, mutect2, varscan2
- FAM160A2 | c.94G>A p.D32N | Missense Mutation (SNP) | VAF 8/180 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99791667; called by muse, mutect2
- FAM50B | c.592C>T p.R198W | Missense Mutation (SNP) | VAF 21/25 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100976496; called by muse, mutect2, varscan2
- FAT3 | c.12925G>A p.A4309T | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV53102655; called by muse, mutect2, varscan2
- FLG | c.7664A>C p.E2555A | Missense Mutation (SNP) | VAF 100/348 reads (29%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as rs752364784, COSV64240831; called by muse, varscan2
- FLG | c.7663G>T p.E2555* | Nonsense Mutation (SNP) | VAF 99/344 reads (29%) | catalogued as rs760728737, COSV64236101, COSV64242040; called by muse, varscan2
- HRNR | c.5648G>T p.G1883V | Missense Mutation (SNP) | VAF 48/549 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.481); catalogued as COSV100912823, COSV64262771; called by muse, mutect2
- IFIT1 | c.1178A>T p.K393I | Missense Mutation (SNP) | VAF 49/138 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.177); catalogued as rs139524521; called by muse, mutect2, varscan2
- IRX1 | c.531G>T p.W177C | Missense Mutation (SNP) | VAF 72/156 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57359141; called by muse, mutect2, varscan2
- ITPRIP | c.82G>A p.A28T | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT tolerated (0.67); PolyPhen benign (0.003); catalogued as rs775756816, COSV53391553; called by muse, mutect2, varscan2
- JAKMIP1 | c.1262G>A p.R421H | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs751046894, COSV51533895; called by muse, mutect2, varscan2
- JHY | c.1771G>A p.V591I | Missense Mutation (SNP) | VAF 76/211 reads (36%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as rs376060402, COSV57072578; called by muse, mutect2, varscan2
- JPH3 | c.733C>T p.R245C | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT tolerated (0.22); PolyPhen benign (0.062); catalogued as rs142136496; called by muse, mutect2, varscan2
- KCNB2 | c.1876G>A p.A626T | Missense Mutation (SNP) | VAF 41/55 reads (75%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.066); catalogued as rs139648032; called by muse, mutect2, varscan2
- KCNS3 | c.727G>T p.A243S | Missense Mutation (SNP) | VAF 60/131 reads (46%) | SIFT tolerated (0.48); PolyPhen benign (0.259); catalogued as COSV58406427; called by muse, mutect2, varscan2
- KIF2B | c.646G>A p.V216I | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); catalogued as rs369005833, COSV52129723; called by muse, mutect2, varscan2
- KRT6C | c.478C>T p.R160W | Missense Mutation (SNP) | VAF 137/304 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs749187914, COSV52877458; called by muse, mutect2, varscan2
- LGALS4 | c.230A>G p.N77S | Missense Mutation (SNP) | VAF 30/78 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs1352893215, COSV100313070; called by muse, varscan2
- LYN | c.868G>A p.E290K | Missense Mutation (SNP) | VAF 47/182 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV70205595; called by muse, mutect2, varscan2
- MMP24 | c.1442G>A p.R481H | Missense Mutation (SNP) | VAF 53/79 reads (67%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.829); catalogued as rs752150455, COSV99863639; called by muse, mutect2, varscan2
- NETO1 | c.1421A>T p.N474I | Missense Mutation (SNP) | VAF 155/185 reads (84%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.939); catalogued as COSV100199411, COSV55005458; called by muse, mutect2, varscan2
- NMBR | c.262G>A p.G88R | Missense Mutation (SNP) | VAF 36/67 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57801082; called by muse, mutect2, varscan2
- NUP107 | c.1985C>A p.T662N | Missense Mutation (SNP) | VAF 47/116 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.15); catalogued as COSV57494434, COSV57496535; called by muse, mutect2, varscan2
- OR5L1 | c.811G>T p.D271Y | Missense Mutation (SNP) | VAF 52/135 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); catalogued as COSV61733625; called by muse, mutect2, varscan2
- OTUD7A | c.1841C>T p.P614L (on ENST00000307050 / NM_001382637.1; = p.P607L on NM_130901.3) | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); catalogued as rs767158283, COSV61038109; called by muse, mutect2, varscan2
- PAPPA2 | c.3132G>C p.L1044F | Missense Mutation (SNP) | VAF 70/149 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.078); catalogued as rs1288806972, COSV100867779, COSV62796105; called by muse, mutect2, varscan2
- PCDHB12 | c.826G>A p.E276K | Missense Mutation (SNP) | VAF 63/162 reads (39%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.044); catalogued as rs1554286731, COSV53395359; called by muse, mutect2, varscan2
- PCDHGB3 | c.457G>T p.A153S | Missense Mutation (SNP) | VAF 48/125 reads (38%) | SIFT tolerated (0.24); PolyPhen benign (0.021); catalogued as rs903944197, COSV53935008; called by muse, mutect2, varscan2
- PIK3R4 | c.3158G>A p.G1053D | Missense Mutation (SNP) | VAF 58/78 reads (74%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.59); catalogued as COSV100768165; called by muse, varscan2
- PLBD2 | c.1215C>T p.P405= | Splice Region (SNP) | VAF 76/166 reads (46%) | catalogued as rs745644781, COSV55106550; called by muse, mutect2, varscan2
- PPP2R2C | c.583C>T p.R195C | Missense Mutation (SNP) | VAF 52/85 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747980900, COSV58671527; called by muse, mutect2, varscan2
- PRKCI | c.61G>T p.D21Y | Missense Mutation (SNP) | VAF 29/78 reads (37%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.34); catalogued as COSV55518148; called by muse, mutect2, varscan2
- PTH2R | c.428G>A p.R143H | Missense Mutation (SNP) | VAF 156/563 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.964); catalogued as rs772635974, COSV55915655; called by muse, mutect2, varscan2
- PTPRD | c.4336C>A p.Q1446K | Missense Mutation (SNP) | VAF 97/225 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV61941109; called by muse, mutect2, varscan2
- RACK1 | c.283G>A p.G95S | Missense Mutation (SNP) | VAF 32/83 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.077); catalogued as COSV65174558; called by muse, mutect2, varscan2
- RGS11 | c.940C>T p.R314W (on ENST00000397770 / NM_183337.3; = p.R293W on NM_003834.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/28 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs747085732, COSV51452388; called by muse, mutect2, varscan2
- ROBO2 | c.1147C>T p.R383C | Missense Mutation (SNP) | VAF 52/107 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs1405895921, COSV59908258; called by muse, mutect2, varscan2
- SEMA3F | c.380G>A p.R127Q | Missense Mutation (SNP) | VAF 45/88 reads (51%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.999); catalogued as rs752415195, COSV50029066; called by muse, mutect2, varscan2
- SH2D3A | c.781G>A p.E261K | Missense Mutation (SNP) | VAF 33/56 reads (59%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs759149797, COSV55585751; called by muse, mutect2, varscan2
- SLC44A2 | c.1445C>T p.P482L | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.658); catalogued as COSV59836376; called by muse, mutect2, varscan2
- SLIT2 | c.164G>A p.R55H | Missense Mutation (SNP) | VAF 14/25 reads (56%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as rs1381268895, COSV56569631; called by muse, mutect2, varscan2
- SORCS3 | c.3015A>C p.L1005F | Missense Mutation (SNP) | VAF 81/169 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63794707; called by muse, mutect2, varscan2
- SPTBN2 | c.6501G>A p.P2167= | Splice Region (SNP) | VAF 56/131 reads (43%) | catalogued as rs1162946011, COSV59450987, COSV59460362; called by muse, mutect2, varscan2
- SULT1C3 | c.29C>T p.T10M | Missense Mutation (SNP) | VAF 154/410 reads (38%) | SIFT tolerated (0.22); PolyPhen benign (0.074); catalogued as rs141315456; called by muse, varscan2
- SYT3 | c.955A>G p.R319G | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.52); catalogued as COSV58896257; called by muse, mutect2, varscan2
- TAL2 | c.119A>G p.K40R | Missense Mutation (SNP) | VAF 14/180 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); catalogued as COSV61883799; called by muse, mutect2
- TAS2R19 | c.318T>G p.C106W | Missense Mutation (SNP) | VAF 83/201 reads (41%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV66828322; called by muse, mutect2, varscan2
- TDRD3 | c.473G>C p.R158T | Missense Mutation (SNP) | VAF 154/275 reads (56%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.563); catalogued as COSV52156072; called by muse, mutect2, varscan2
- TTN | c.97271C>T p.S32424L (on ENST00000591111; = p.S25000L on NM_003319.4) | Missense Mutation (SNP) | VAF 36/63 reads (57%) | PolyPhen benign (0.039); catalogued as rs769936820, COSV100592112; called by muse, mutect2, varscan2
- TTN | c.326G>A p.R109Q | Missense Mutation (SNP) | VAF 42/92 reads (46%) | PolyPhen probably damaging (0.996); catalogued as rs766434493, COSV100589320, COSV59935368; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- UGT2B17 | c.116T>C p.M39T | Missense Mutation (SNP) | VAF 26/191 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.809); catalogued as COSV100497155; called by muse, mutect2
- UNC13A | c.2488G>A p.V830M | Missense Mutation (SNP) | VAF 19/98 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.15); catalogued as rs760950869, COSV53190047; called by muse, mutect2, varscan2
- UNC5CL | c.413G>A p.R138Q | Missense Mutation (SNP) | VAF 41/44 reads (93%) | SIFT tolerated (0.53); PolyPhen benign (0.015); catalogued as rs765497708, COSV55109710, COSV99770591; called by muse, mutect2, varscan2
- UPF1 | c.1211T>C p.I404T (on ENST00000599848 / NM_001297549.2; = p.I393T on NM_002911.4) | Missense Mutation (SNP) | VAF 49/163 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.401); catalogued as COSV53195750; called by muse, mutect2, varscan2
- UTP3 | c.98G>T p.G33V | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.006); catalogued as COSV54660993; called by muse, mutect2, varscan2
- ZFP30 | c.1457G>A p.R486K | Missense Mutation (SNP) | VAF 77/196 reads (39%) | SIFT tolerated (0.22); PolyPhen benign (0.054); catalogued as rs777324427, COSV63622379, COSV63622436; called by muse, mutect2, varscan2
- FBN2 | c.6386G>A p.S2129N | Missense Mutation (SNP) | VAF 12/300 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.044); called by muse, mutect2
- IHH | c.757_760del p.R253* | Frame Shift Del (DEL) | VAF 66/106 reads (62%) | called by mutect2, pindel, varscan2
- PIP5K1C | c.1585T>C p.S529P | Missense Mutation (SNP) | VAF 12/121 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.827); called by muse, mutect2
- ALPK3 | c.3549T>A p.P1183= | Silent (SNP) | VAF 13/18 reads (72%) | catalogued as COSV51932693; called by muse, mutect2, varscan2
- AMOTL1 | c.2703G>A p.T901= | Silent (SNP) | VAF 20/47 reads (43%) | catalogued as rs755363731, COSV58566202; called by muse, mutect2, varscan2
- C9orf135 | c.285A>G p.E95= | Silent (SNP) | VAF 88/179 reads (49%) | catalogued as COSV65875291; called by muse, mutect2, varscan2
- CBX7 | c.555G>A p.A185= | Silent (SNP) | VAF 8/11 reads (73%) | catalogued as rs765884458, COSV53358864; called by muse, mutect2, varscan2
- CCDC40 | c.1710C>T p.T570= | Silent (SNP) | VAF 40/97 reads (41%) | catalogued as COSV100884248, COSV66474313; called by muse, mutect2, varscan2
- CDAN1 | c.2076C>T p.T692= | Silent (SNP) | VAF 38/81 reads (47%) | catalogued as rs143566164; ClinVar: likely benign; called by muse, mutect2, varscan2
- DUSP21 | c.180C>T p.N60= | Silent (SNP) | VAF 62/70 reads (89%) | catalogued as rs1414594359, COSV59134489; called by muse, mutect2, varscan2
- FAT1 | c.1068T>G p.T356= | Silent (SNP) | VAF 88/132 reads (67%) | catalogued as rs374806294; called by muse, mutect2
- FLG | c.7665G>A p.E2555= | Silent (SNP) | VAF 104/358 reads (29%) | catalogued as rs767356239, COSV64240826, COSV64244727; called by muse, varscan2
- FLT4 | c.2721C>T p.L907= | Silent (SNP) | VAF 17/43 reads (40%) | catalogued as COSV56106274, COSV99988855; called by muse, mutect2, varscan2
- FRMD1 | c.621C>T p.F207= | Silent (SNP) | VAF 21/41 reads (51%) | catalogued as rs766370593, COSV51961516; called by muse, mutect2, varscan2
- GJC1 | c.582G>T p.G194= | Silent (SNP) | VAF 64/165 reads (39%) | catalogued as COSV57911129; called by muse, mutect2, varscan2
- GRM4 | c.2175G>A p.S725= | Silent (SNP) | VAF 38/48 reads (79%) | catalogued as rs1351192445, COSV65212992; called by muse, mutect2, varscan2
- HOXD1 | c.492G>A p.P164= | Silent (SNP) | VAF 32/85 reads (38%) | catalogued as rs766880295, COSV58924737; called by muse, mutect2, varscan2
- HYAL2 | c.738G>A p.T246= | Silent (SNP) | VAF 12/35 reads (34%) | catalogued as rs149978009; called by muse, mutect2, varscan2
- INPP5F | c.3036G>A p.S1012= | Silent (SNP) | VAF 98/204 reads (48%) | catalogued as rs563867547, COSV62820938; called by muse, mutect2, varscan2
- KIAA1210 | c.1878C>T p.F626= | Silent (SNP) | VAF 160/215 reads (74%) | catalogued as rs376389367, COSV101273867, COSV68175532; called by muse, mutect2, varscan2
- KLHL1 | c.513C>A p.G171= | Silent (SNP) | VAF 80/135 reads (59%) | catalogued as COSV100916916; called by muse, mutect2, varscan2
- MYH7 | c.1446C>T p.N482= | Silent (SNP) | VAF 90/112 reads (80%) | catalogued as rs775745470, COSV62516531; ClinVar: likely benign; called by muse, mutect2, varscan2
- N4BP2L2 | c.1518T>G p.T506= | Silent (SNP) | VAF 438/708 reads (62%) | catalogued as COSV57228153; called by muse, mutect2, varscan2
- NID1 | c.990C>T p.S330= | Silent (SNP) | VAF 28/72 reads (39%) | catalogued as rs1207948951, COSV51619013; called by muse, mutect2, varscan2
- OR2T11 | c.795C>T p.P265= | Silent (SNP) | VAF 46/59 reads (78%) | catalogued as rs150601677, COSV58185492; called by muse, mutect2, varscan2
- PACC1 | c.837A>G p.Q279= | Silent (SNP) | VAF 170/424 reads (40%) | catalogued as rs372765144; called by muse, mutect2, varscan2
- PAK5 | c.1260C>T p.S420= | Silent (SNP) | VAF 24/82 reads (29%) | catalogued as rs367976201, COSV62022631; called by muse, mutect2, varscan2
- PLEC | c.9438C>T p.D3146= (on ENST00000322810 / NM_201380.4; = p.D3036= on NM_000445.5) | Silent (SNP) | VAF 16/37 reads (43%) | catalogued as rs782802729, COSV59607546; ClinVar: likely benign; called by muse, mutect2, varscan2
- PTPRE | c.855C>T p.D285= | Silent (SNP) | VAF 11/22 reads (50%) | catalogued as rs201293516, COSV54549943; called by muse, mutect2, varscan2
- RET | c.2418C>T p.Y806= | Silent (SNP) | VAF 11/23 reads (48%) | catalogued as rs553418132, COSV60692363; ClinVar: benign / likely benign; called by muse, mutect2, varscan2
- RTP5 | c.498C>T p.A166= | Silent (SNP) | VAF 19/39 reads (49%) | catalogued as COSV58319730; called by muse, mutect2, varscan2
- SFSWAP | c.2121G>A p.E707= | Silent (SNP) | VAF 28/58 reads (48%) | catalogued as COSV55521513; called by muse, mutect2, varscan2
- SLC4A3 | c.2151C>T p.F717= | Silent (SNP) | VAF 39/57 reads (68%) | catalogued as rs370555923; called by muse, mutect2, varscan2
- SOX13 | c.1074G>C p.R358= | Silent (SNP) | VAF 54/94 reads (57%) | catalogued as COSV65826635; called by muse, mutect2, varscan2
- TGFBRAP1 | c.252G>A p.A84= | Silent (SNP) | VAF 20/42 reads (48%) | catalogued as rs756300308, COSV51511610; called by muse, mutect2, varscan2
- TIMELESS | c.1743G>C p.V581= | Silent (SNP) | VAF 20/61 reads (33%) | catalogued as COSV57510914; called by muse, mutect2, varscan2
- TTN | c.5298T>A p.V1766= (on ENST00000591111; = p.V1720= on NM_003319.4) | Silent (SNP) | VAF 32/73 reads (44%) | catalogued as rs1197807865, COSV60009850; called by muse, mutect2, varscan2
- WWC3 | c.2085G>A p.P695= | Silent (SNP) | VAF 55/73 reads (75%) | catalogued as rs762039453, COSV66502801; called by muse, mutect2, varscan2
- ZNF514 | c.231G>A p.R77= | Silent (SNP) | VAF 35/96 reads (36%) | catalogued as COSV99727551; called by muse, mutect2, varscan2
- ANKS1B | c.2420-49G>A | Intron (SNP) | VAF 42/105 reads (40%) | catalogued as rs757898757, COSV60361780; called by muse, mutect2, varscan2
